Somatic mutation profile of tumor specimen 0DQ8WX from CCDI case PBCCDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 22.7 years (8,287 days).
Specimen 0DQ8WX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f88a84-0ab7-4063-9286-3277dad5b230.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ8YB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cceb287f-a9e6-4c99-ab86-7d80edf2909f

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 3, Intron 2, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 136/343 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1QTNF6 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.664); catalogued as rs1569062460; called by muse, mutect2, varscan2
- CAPN6 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 238/258 reads (92%) | catalogued as rs750201143; called by muse, mutect2, varscan2
- MCTP1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1485288169, COSV56517822; called by muse, mutect2, varscan2
- PCLO | c.5083G>A p.E1695K | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs781119407, COSV61625807; called by muse, mutect2, varscan2
- AKAP1 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CD79A | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- CNTNAP1 | c.1843T>A p.C615S | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTRL | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 81/184 reads (44%) | called by muse, mutect2, varscan2
- FER1L6 | c.5041T>A p.L1681I | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 18/487 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LONRF2 | c.2103G>T p.W701C | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH15 | c.4952C>A p.A1651E | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- OR56A3 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POFUT1 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZCWPW2 | c.432dup p.P145Sfs*16 | Frame Shift Ins (INS) | VAF 100/210 reads (48%) | called by mutect2, varscan2
- FOCAD | c.2148C>T p.N716= | Silent (SNP) | VAF 22/539 reads (4%) | catalogued as rs1172827814; called by muse, mutect2
- OR3A1 | c.669C>T p.H223= | Silent (SNP) | VAF 103/265 reads (39%) | catalogued as rs199711058; called by muse, mutect2, varscan2
- PEX5L | c.22-1517C>T | Intron (SNP) | VAF 121/299 reads (40%) | catalogued as rs991749784; called by muse, mutect2, varscan2
- TEDC1 | c.148-25A>G | Intron (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
